Somatic mutation profile of tumor specimen ALCH-AEEH-TTP1-A (aliquot ALCH-AEEH-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AEEH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.3 years (22,381 days).
Specimen ALCH-AEEH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 027e4352-8645-4f93-a390-7a81c5a6ef31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEEH-NB1-A (Blood Derived Normal), aliquot ALCH-AEEH-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/500c8cb9-0f05-429d-bebb-bc6a10c728e7

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASMT | c.887C>T p.T296M (on ENST00000381229; = p.T324M on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/599 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs752176281, CM127797; called by muse, mutect2
- HELB | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs755473288, COSV104372164; called by muse, mutect2
- COG1 | c.2338G>A p.V780I | Missense Mutation (SNP) | VAF 26/909 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2
- RBM10 | c.1767C>G p.Y589* | Nonsense Mutation (SNP) | VAF 11/229 reads (5%) | called by muse, mutect2
- GPR37L1 | c.1212C>T p.S404= | Silent (SNP) | VAF 12/350 reads (3%) | called by muse, mutect2
- PSG9 | c.1239C>T p.V413= | Silent (SNP) | VAF 15/213 reads (7%) | catalogued as COSV99392032; called by muse, mutect2
